Somatic mutation profile of tumor specimen TCGA-AF-A56L-01A (aliquot TCGA-AF-A56L-01A-31D-A38X-10) from TCGA case TCGA-AF-A56L, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 48.6 years (17,734 days).
Specimen TCGA-AF-A56L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26ab10eb-280c-4f58-ae2b-af7cac123ab2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-A56L-10A (Blood Derived Normal), aliquot TCGA-AF-A56L-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1320ce12-4bc7-4741-9f49-3ea1f70b26c8

The open-access MAF lists 138 somatic variants for this specimen: 107 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 27, Nonsense Mutation 8, Splice Site 2, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1, Intron 1, RNA 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 150/373 reads (40%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 34/70 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD3 | c.74T>A p.V25E | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100004586; called by muse, mutect2, varscan2
- ACSBG1 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs750963555, COSV51908982; called by muse, mutect2, varscan2
- AGRN | c.5387G>A p.R1796H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs774881136, COSV101039097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.2567A>G p.N856S | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs1283444068, COSV100663137, COSV62353453; called by muse, mutect2, varscan2
- ANKLE1 | c.1357C>A p.P453T (on ENST00000394458; = p.P399T on NM_152363.6) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.454); catalogued as COSV63921304; called by muse, mutect2, varscan2
- APC | c.4142dup p.L1382Tfs*4 | Frame Shift Ins (INS) | VAF 23/114 reads (20%) | catalogued as COSV57392488; called by mutect2, pindel, varscan2
- ARHGAP24 | c.2046C>A p.S682R (on ENST00000395184 / NM_001025616.3; = p.S589R on NM_031305.3) | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99982472; called by muse, mutect2, varscan2
- ATG2A | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs767644437, COSV101034813; called by muse, mutect2, varscan2
- BOP1 | c.666G>A p.P222= | Splice Region (SNP) | VAF 13/107 reads (12%) | catalogued as rs1261251013; called by muse, mutect2, varscan2
- CCDC85A | c.1123G>T p.G375* | Nonsense Mutation (SNP) | VAF 27/114 reads (24%) | catalogued as COSV101339564; called by muse, mutect2, varscan2
- CD3G | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs750576395, COSV99416914; called by muse, mutect2, varscan2
- CDC42BPA | c.3764C>A p.T1255N (on ENST00000334218 / NM_001366019.2; = p.T1242N on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.267); catalogued as COSV100506931; called by muse, varscan2
- CNTN3 | c.2389T>A p.S797T | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV99726128; called by muse, mutect2, varscan2
- COL7A1 | c.7510C>T p.R2504C | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs201897441, COSV60403385; ClinVar: uncertain significance; called by muse, mutect2
- COPB1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1373598124, COSV51449913; called by muse, varscan2
- CPB1 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV99294560; called by muse, mutect2, varscan2
- CPNE4 | c.939T>G p.D313E | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101456816; called by muse, mutect2, varscan2
- CPZ | c.1321G>A p.G441R (on ENST00000360986 / NM_001014447.3; = p.G430R on NM_003652.3) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); catalogued as rs775707132, COSV100249293, COSV59921617; called by muse, mutect2, varscan2
- DISP1 | c.1222C>A p.Q408K | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as COSV99452232; called by muse, mutect2, varscan2
- DOCK3 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | catalogued as COSV56538547, COSV56539664; called by muse, mutect2
- ERBB4 | c.1760C>A p.P587Q | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV99633199; called by muse, mutect2, varscan2
- F5 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs748844637, COSV100889253; called by muse, mutect2, varscan2
- FAM124A | c.800C>T p.T267M (on ENST00000322475 / NM_001242312.2; = p.T303M on NM_145019.4) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775058541, COSV54475891; called by muse, mutect2, varscan2
- FAM186B | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs773097118, COSV99220420; called by muse, mutect2, varscan2
- FBXO34 | c.572A>T p.Y191F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV58256081; called by muse, mutect2, varscan2
- FGA | c.2059C>T p.R687W | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762511080, COSV57399681; called by muse, mutect2, varscan2
- FGFR1 | c.448+1G>A p.X150_splice (on ENST00000447712 / NM_023110.3; = p.X61_splice on NM_023105.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 86/120 reads (72%) | catalogued as rs376416531, COSV58341024; called by muse, varscan2
- FRAS1 | c.8242G>T p.V2748L | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV53631758; called by muse, mutect2, varscan2
- GPR6 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); catalogued as rs955696746, COSV99254581; called by muse, mutect2, varscan2
- HTR5A | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs780790670, COSV55282302, COSV55284114; called by muse, mutect2, varscan2
- HYDIN | c.15248G>A p.G5083E | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101125227; called by muse, mutect2, varscan2
- INPP5D | c.2598C>G p.D866E (on ENST00000445964 / NM_001017915.3; = p.D865E on NM_005541.5) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.549); catalogued as COSV64039016; called by muse, mutect2, varscan2
- IPCEF1 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99500546; called by muse, mutect2, varscan2
- KLHDC8B | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs139371579; called by muse, mutect2, varscan2
- L3MBTL1 | c.2119G>A p.G707S (on ENST00000418998 / NM_001377303.1; = p.G617S on NM_015478.7) | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.451); catalogued as rs1334583086, COSV64228379; called by muse, mutect2
- LARGE2 | c.563G>C p.S188T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV57657963; called by muse, mutect2, varscan2
- LRFN5 | c.1647G>T p.M549I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV53244291, COSV53268624; called by muse, mutect2, varscan2
- MAP3K4 | c.3701G>A p.R1234Q | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs971378102, COSV62337207; called by muse, mutect2, varscan2
- MFAP3L | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV100852714; called by muse, mutect2, varscan2
- MKLN1 | c.1614A>T p.E538D | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1469251060, COSV100760019; called by muse, mutect2, varscan2
- MRO | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370546021; called by muse, mutect2, varscan2
- NAALAD2 | c.1233G>T p.W411C | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100428842; called by muse, mutect2, varscan2
- NBEA | c.3392C>A p.T1131K | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.039); catalogued as COSV100084331; called by muse, mutect2
- NINL | c.3880C>T p.R1294W | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as rs759311453, COSV99626349; called by muse, mutect2, varscan2
- NPHS1 | c.3301A>G p.T1101A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as rs755336619, COSV100800277; called by muse, mutect2, varscan2
- NYX | c.1345C>A p.R449S | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV100699470, COSV61180901; called by muse, mutect2, varscan2
- OBSCN | c.11947C>T p.R3983* | Nonsense Mutation (SNP) | VAF 47/93 reads (51%) | catalogued as rs766814997, COSV52737807; called by muse, mutect2, varscan2
- OOEP | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as rs1054721483, COSV64859273; called by muse, mutect2, varscan2
- OR11H4 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59560456; called by muse, mutect2, varscan2
- PAPPA2 | c.285C>A p.S95R | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV62783087; called by muse, mutect2, varscan2
- PARP14 | c.5018A>G p.Q1673R | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.23); catalogued as COSV71735277; called by muse, mutect2, varscan2
- PDZD2 | c.2774G>T p.G925V | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99226765; called by muse, mutect2, varscan2
- PEG3 | c.3985A>C p.I1329L | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs370009140; called by muse, mutect2
- PHLDB2 | c.2464G>A p.V822I (on ENST00000393925 / NM_001134439.2; = p.V779I on NM_145753.2) | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1374135138, COSV101208714; called by muse, mutect2
- PLB1 | c.4198C>T p.R1400W | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs765736021, COSV59824560; called by muse, mutect2
- POM121 | c.1274A>C p.Q425P (on ENST00000434423; = p.Q160P on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs782510843, COSV57515432; called by muse, mutect2, varscan2
- PPM1A | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.989); catalogued as COSV100349469; called by muse, mutect2
- PPM1L | c.91A>T p.I31F | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV101534472; called by muse, mutect2, varscan2
- PRDM14 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1563439440, COSV52573094, COSV52574077; called by muse, mutect2
- PRKDC | c.6640C>T p.R2214* | Nonsense Mutation (SNP) | VAF 12/134 reads (9%) | catalogued as COSV58042368; called by muse, mutect2
- PRRC2B | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); catalogued as COSV61941021; called by muse, mutect2, varscan2
- PRSS38 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754529751, COSV64541070, COSV64541613; called by muse, mutect2, varscan2
- RABGAP1L | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs150517419; called by muse, mutect2, varscan2
- RASGRP3 | c.92A>G p.N31S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV67823894; called by muse, mutect2
- RGL3 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV66510488; called by muse, mutect2, varscan2
- RIBC2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs200022735; called by muse, mutect2
- RPL10L | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53561611; called by muse, mutect2, varscan2
- RTL9 | c.3274A>G p.M1092V | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as COSV101511803; called by muse, mutect2, varscan2
- RYR3 | c.3728C>T p.T1243M | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); catalogued as rs550824274, COSV101214644; called by muse, mutect2
- SBNO1 | c.1029A>T p.R343S (on ENST00000420886; = p.R342S on NM_018183.5) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99929725; called by muse, mutect2, varscan2
- SHROOM2 | c.2339C>A p.P780H | Missense Mutation (SNP) | VAF 39/327 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV66609286; called by muse, mutect2, varscan2
- SIRPB1 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53537572, COSV53540035; called by muse, mutect2, varscan2
- SLC10A2 | c.765C>G p.C255W | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV99808288; called by muse, mutect2
- SLC25A40 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV100353823; called by muse, mutect2
- SLC35D2 | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV99481061; called by muse, mutect2, varscan2
- SLC6A14 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 43/377 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.315); catalogued as COSV100903235; called by muse, mutect2, varscan2
- SLC9A8 | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs746946184, COSV100846241; called by muse, mutect2, varscan2
- SLITRK4 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.195); catalogued as rs782237496, COSV62022135; called by muse, mutect2
- SMARCA1 | c.1255C>A p.L419M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.609); catalogued as COSV100946728; called by muse, mutect2, varscan2
- SOX6 | c.1471G>T p.G491W (on ENST00000528429 / NM_001145819.2; = p.G464W on NM_017508.3) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100323295; called by muse, mutect2, varscan2
- SPHKAP | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs762864182, COSV60885134; called by muse, mutect2, varscan2
- SPTB | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV101072414; called by muse, mutect2, varscan2
- SYNE1 | c.24347C>T p.A8116V (on ENST00000367255 / NM_182961.4; = p.A8045V on NM_033071.3) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs781159250, COSV55025559; called by muse, mutect2, varscan2
- TACR3 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.038); catalogued as COSV59201024; called by muse, mutect2, varscan2
- TBC1D13 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as COSV56354362; called by muse, mutect2, varscan2
- THOC2 | c.2122C>A p.Q708K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV55552302; called by muse, mutect2, varscan2
- TMEM200A | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as COSV51649616, COSV99760128; called by muse, mutect2, varscan2
- TNS1 | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as rs751419226, COSV50701348, COSV99410028; called by muse, mutect2, varscan2
- TOPORS | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs755081657, COSV62117738; called by muse, mutect2, varscan2
- TRPC1 | c.1835G>C p.S612T (on ENST00000476941 / NM_001251845.2; = p.S578T on NM_003304.4) | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.089); catalogued as COSV99859372; called by muse, mutect2, varscan2
- TXNDC2 | c.1614C>A p.C538* (on ENST00000306084 / NM_001098529.2; = p.C471* on NM_032243.6) | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100046597, COSV60152449; called by mutect2, varscan2
- USP9X | c.6517C>T p.R2173C | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100200122; called by muse, mutect2
- WDR13 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.532); catalogued as rs1163033477, COSV54331692; called by muse, mutect2, varscan2
- ZFPM1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs990429969, COSV100128760; called by muse, mutect2, varscan2
- ZFPM2 | c.1407A>C p.K469N | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.321); catalogued as COSV65874999; called by muse, mutect2, varscan2
- ZNF304 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs759725667, COSV56583271; called by muse, mutect2, varscan2
- ZNF521 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV100833431; called by muse, mutect2, varscan2
- ZNF646 | c.5236C>T p.R1746W | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs548921628, COSV99761989; called by muse, mutect2, varscan2
- ZNF667 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as COSV52636115, COSV99410981; called by muse, mutect2
- ZNF672 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs1266709676, COSV100129401; called by muse, mutect2, varscan2
- ZNF75D | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV100883697; called by muse, mutect2
- ZSCAN22 | c.1238G>A p.C413Y | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100308520; called by muse, mutect2, varscan2
- MRPL44 | c.754_755insAAG p.S251_A252insE | In Frame Ins (INS) | VAF 26/85 reads (31%) | called by mutect2, pindel, varscan2
- OSBPL8 | c.217+1_217+5del p.X73_splice | Splice Site (DEL) | VAF 10/95 reads (11%) | called by mutect2, pindel
- PTPRK | c.1340C>A p.P447H | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADGRB1 | c.663C>A p.G221= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100030402; called by muse, mutect2, varscan2
- AIFM1 | c.1371C>T p.H457= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as rs1278945294, COSV54856764; called by muse, mutect2, varscan2
- AKAP6 | c.2794C>T p.L932= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV99804572; called by muse, mutect2, varscan2
- ALKAL2 | c.408G>A p.R136= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV99681832; called by muse, mutect2, varscan2
- ARAF | c.1587G>A p.P529= | Silent (SNP) | VAF 31/204 reads (15%) | catalogued as rs1261254398, COSV51693135; called by muse, mutect2, varscan2
- CDH4 | c.480C>T p.N160= | Silent (SNP) | VAF 56/391 reads (14%) | catalogued as rs149210026; called by muse, mutect2, varscan2
- COPG2 | c.294C>T p.I98= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as COSV100449733; called by muse, mutect2
- DAPK1 | c.240C>T p.H80= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs36207429, COSV63783823; called by muse, mutect2, varscan2
- DIPK2B | c.591C>A p.I197= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as COSV100933493; called by muse, mutect2, varscan2
- DRC7 | c.624C>T p.N208= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs201161084, COSV61052909; called by muse, mutect2, varscan2
- F7 | c.159C>T p.G53= | Silent (SNP) | VAF 40/260 reads (15%) | catalogued as rs763156842, COSV60647260; called by muse, mutect2, varscan2
- GGT7 | c.252G>A p.P84= | Silent (SNP) | VAF 40/251 reads (16%) | catalogued as COSV100322218; called by muse, mutect2, varscan2
- HNRNPU | c.1044C>T p.G348= (on ENST00000283179; = p.G410= on NM_004501.3) | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as rs754530060, COSV99310733; called by muse, mutect2
- KLHDC4 | c.1536C>T p.S512= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs556357664, COSV99566365; called by muse, mutect2, varscan2
- MAGEB3 | c.951A>G p.R317= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV100854603, COSV100854820; called by muse, mutect2
- MTA2 | c.1827C>T p.A609= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV99545630; called by muse, mutect2, varscan2
- NFKB1 | c.1572C>T p.D524= (on ENST00000394820 / NM_001382627.1; = p.D525= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs1057013934, COSV99897900; called by muse, mutect2, varscan2
- NHS | c.435C>T p.H145= | Silent (SNP) | VAF 29/206 reads (14%) | catalogued as COSV101197006; called by muse, mutect2, varscan2
- NKAPL | c.417G>A p.P139= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV59197910; called by muse, mutect2, varscan2
- NUFIP2 | c.1728G>A p.L576= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV99837655; called by muse, mutect2, varscan2
- PAK2 | c.627A>G p.S209= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as COSV100506368; called by muse, mutect2
- PPM1L | c.462C>T p.Y154= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs755440707, COSV99862234; called by muse, mutect2, varscan2
- PPP1R3A | c.3324A>G p.L1108= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV99494350; called by muse, mutect2, varscan2
- RBP3 | c.885G>A p.T295= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs782470605; called by muse, mutect2, varscan2
- SERPINA5 | c.858G>A p.T286= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as rs138001666; called by muse, mutect2, varscan2
- TRPA1 | c.1281T>C p.G427= | Silent (SNP) | VAF 46/326 reads (14%) | catalogued as COSV100085228; called by muse, mutect2, varscan2
- ZNF521 | c.2658C>T p.Y886= | Silent (SNP) | VAF 44/78 reads (56%) | catalogued as rs748507168, COSV64122835; called by muse, mutect2, varscan2
- ACSL6 | chr5:131947637 A>C | 3'Flank (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- DOCK9-DT | chr13:99086284 G>A | 5'Flank (SNP) | VAF 12/83 reads (14%) | catalogued as rs1197844880, COSV59637952; called by muse, mutect2, varscan2
- LPAL2 | n.559C>A | RNA (SNP) | VAF 49/128 reads (38%) | called by muse, mutect2, varscan2
- SLIT3 | c.198-12177G>A | Intron (SNP) | VAF 19/120 reads (16%) | catalogued as rs890116781, COSV100270030; called by muse, mutect2
